Somatic mutation profile of tumor specimen TCGA-CJ-5679-01A (aliquot TCGA-CJ-5679-01A-11D-1534-10) from TCGA case TCGA-CJ-5679, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 73.5 years (26,858 days).
Specimen TCGA-CJ-5679-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13a46dc8-8719-4ff5-b34f-a533df101fa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5679-11A (Solid Tissue Normal), aliquot TCGA-CJ-5679-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37d92ba7-5693-4f91-89c3-e5bff249df46

The open-access MAF lists 93 somatic variants for this specimen: 77 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 15, Frame Shift Del 7, Nonsense Mutation 2, Splice Site 2, Splice Region 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 122/201 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RBFOX1 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs372761949; ClinVar: pathogenic; called by muse, mutect2
- ADGRL2 | c.3737A>C p.Q1246P (on ENST00000370717 / NM_001366005.1; = p.Q1190P on NM_012302.4) | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV54655117; called by muse, mutect2, varscan2
- ATP2B1 | c.2414T>A p.L805Q | Missense Mutation (SNP) | VAF 206/478 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV53804463; called by muse, mutect2, varscan2
- ATXN7 | c.2077C>A p.Q693K | Missense Mutation (SNP) | VAF 100/139 reads (72%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV55748534; called by muse, mutect2, varscan2
- C11orf42 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as rs1037161461, COSV56409886; called by muse, mutect2, varscan2
- C1R | c.417T>A p.N139K (on ENST00000536053 / NM_001354346.2; = p.N125K on NM_001733.7) | Missense Mutation (SNP) | VAF 86/233 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV56923655; called by muse, mutect2, varscan2
- C7orf50 | c.433C>A p.L145M | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1436506757, COSV62473172; called by muse, mutect2, varscan2
- CCDC144A | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 183/555 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV61402562; called by muse, mutect2, varscan2
- CHD7 | c.7892G>A p.R2631Q | Missense Mutation (SNP) | VAF 14/267 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1327851196, COSV71107546; called by muse, mutect2
- CHPT1 | c.1118T>A p.I373N | Missense Mutation (SNP) | VAF 341/901 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57148354; called by muse, mutect2, varscan2
- CNGB1 | c.847T>A p.S283T | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.037); catalogued as COSV51898179; called by muse, mutect2, varscan2
- COL27A1 | c.4414G>T p.G1472W | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61922147; called by muse, mutect2, varscan2
- CRPPA | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 187/381 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV67904412; called by muse, mutect2, varscan2
- CSMD3 | c.4826C>T p.P1609L (on ENST00000297405 / NM_001363185.1; = p.P1505L on NM_052900.3) | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1196558347, COSV52113614; called by muse, mutect2
- DAW1 | c.120T>A p.D40E | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV59363934; called by muse, mutect2, varscan2
- DHX37 | c.2869-1G>A p.X957_splice | Splice Site (SNP) | VAF 168/421 reads (40%) | catalogued as COSV58132362; called by muse, mutect2, varscan2
- DNAH17 | c.10297G>A p.G3433S | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1167643001, COSV67750368; called by muse, mutect2, varscan2
- DNAI4 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1303983447, COSV64020827; called by muse, mutect2
- DOCK5 | c.1924A>T p.N642Y | Missense Mutation (SNP) | VAF 145/532 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV52396831; called by muse, mutect2, varscan2
- DPP10 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 51/203 reads (25%) | catalogued as COSV59667578; called by muse, mutect2, varscan2
- EGF | c.282A>T p.E94D | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV54476171; called by muse, mutect2, varscan2
- EIF3L | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1432384069, COSV67739424; called by muse, mutect2, varscan2
- EIPR1 | c.497A>G p.E166G | Missense Mutation (SNP) | VAF 91/187 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV66128287; called by muse, mutect2, varscan2
- EIPR1 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 89/185 reads (48%) | catalogued as COSV66128297; called by muse, mutect2, varscan2
- ERBB4 | c.2395A>T p.M799L | Missense Mutation (SNP) | VAF 89/179 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV61467605; called by muse, mutect2, varscan2
- ERCC6 | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.132); catalogued as COSV63388192; called by muse, mutect2
- FAM83B | c.2990G>A p.R997Q | Missense Mutation (SNP) | VAF 76/113 reads (67%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.805); catalogued as rs146473058, COSV100175000; called by muse, mutect2, varscan2
- FLACC1 | c.778A>G p.K260E | Missense Mutation (SNP) | VAF 189/351 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV53782187; called by muse, mutect2, varscan2
- FMN2 | c.4406G>A p.R1469H | Missense Mutation (SNP) | VAF 227/532 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs745747440, COSV60419249; called by muse, mutect2, varscan2
- FRK | c.666A>T p.K222N | Missense Mutation (SNP) | VAF 105/167 reads (63%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV73383831; called by muse, mutect2, varscan2
- GABRA4 | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as COSV51923253; called by muse, mutect2
- GAS7 | c.460G>A p.G154S (on ENST00000432992 / NM_201433.2; = p.G94S on NM_201432.2) | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs545830122, COSV60432338; called by muse, mutect2, varscan2
- GP1BA | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as rs755916282, COSV56698731; called by muse, mutect2, varscan2
- HEXA | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs552505619, COSV51504943, COSV51507891; ClinVar: uncertain significance; called by muse, mutect2
- HRNR | c.2322C>G p.H774Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1176404445, COSV64264245; called by mutect2, varscan2
- HSPA9 | c.1196T>C p.V399A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as rs1316765038, COSV51863447; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs369991706; called by muse, mutect2, varscan2
- KAZN | c.1548C>T p.S516= | Splice Region (SNP) | VAF 17/21 reads (81%) | catalogued as rs1479195909, COSV65715358, COSV65717733; called by muse, mutect2, varscan2
- KCTD20 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs576744140, COSV54802322; called by muse, mutect2, varscan2
- KIF1C | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57902844; called by muse, mutect2, varscan2
- MAB21L2 | c.380A>T p.K127M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58260959; called by muse, mutect2, varscan2
- MICAL2 | c.5087A>C p.E1696A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); catalogued as COSV56284446; called by muse, mutect2
- MRTFB | c.1049A>T p.N350I | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV57956408; called by muse, mutect2, varscan2
- MTMR3 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 89/175 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60302118; called by muse, mutect2, varscan2
- MYO18A | c.5389C>G p.L1797V | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as COSV62863270; called by muse, mutect2, varscan2
- OR2A12 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV68821080, COSV68822144; called by muse, mutect2, varscan2
- PILRA | c.632T>G p.I211S | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV52199390; called by muse, mutect2, varscan2
- SBF2 | c.2917A>C p.T973P | Missense Mutation (SNP) | VAF 141/473 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV56292647; called by muse, mutect2, varscan2
- SBNO1 | c.1591T>C p.Y531H (on ENST00000420886; = p.Y530H on NM_018183.5) | Missense Mutation (SNP) | VAF 138/298 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57339346; called by muse, mutect2, varscan2
- SECISBP2L | c.1961G>T p.S654I (on ENST00000559471 / NM_001193489.2; = p.S609I on NM_014701.4) | Missense Mutation (SNP) | VAF 115/570 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55932986; called by muse, mutect2, varscan2
- SENP5 | c.1909C>G p.L637V | Missense Mutation (SNP) | VAF 285/413 reads (69%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV60206238; called by muse, mutect2, varscan2
- SLC30A5 | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 339/1269 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV67448835; called by muse, mutect2, varscan2
- SLC37A2 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs749361924, COSV53520728; called by muse, mutect2, varscan2
- SLC5A11 | c.1777G>A p.V593I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs572775623, COSV61740330; called by muse, mutect2, varscan2
- SRRM4 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 84/395 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs765750545, COSV57409719; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3763G>A p.V1255M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs749324062, COSV64100172; called by muse, mutect2, varscan2
- TNNI3K | c.2490C>A p.S830R | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV58546976; called by muse, mutect2, varscan2
- TPR | c.5129C>G p.T1710S | Missense Mutation (SNP) | VAF 237/606 reads (39%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.942); catalogued as COSV100823701, COSV66599712; called by muse, mutect2, varscan2
- TRBV19 | c.171C>G p.D57E | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1266668768; called by muse, mutect2, varscan2
- TRIM22 | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 404/906 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as rs370736499; called by muse, mutect2, varscan2
- TSPYL2 | c.1834G>T p.D612Y | Missense Mutation (SNP) | VAF 147/180 reads (82%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.178); catalogued as rs375418655, COSV64920924; called by muse, mutect2, varscan2
- USP25 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs769585815, COSV53481661; called by muse, mutect2, varscan2
- WDR11 | c.823G>C p.V275L | Missense Mutation (SNP) | VAF 88/423 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV54785891; called by muse, mutect2, varscan2
- XIRP2 | c.5385G>C p.Q1795H (on ENST00000628543; = p.Q1970H on NM_152381.6) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54685321; called by muse, mutect2, varscan2
- XPNPEP2 | c.834C>A p.N278K | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV64368471; called by muse, mutect2, varscan2
- ZNF226 | c.1570G>C p.V524L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56196026; called by muse, mutect2, varscan2
- ZNF610 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV58343762; called by muse, mutect2, varscan2
- ATP6V1D | c.71del p.K24Rfs*10 | Frame Shift Del (DEL) | VAF 123/449 reads (27%) | called by mutect2, pindel, varscan2
- DCUN1D1 | c.209_220+18del p.X70_splice | Splice Site (DEL) | VAF 57/123 reads (46%) | called by mutect2, pindel
- KCNAB2 | c.970del p.A324Pfs*69 | Frame Shift Del (DEL) | VAF 49/92 reads (53%) | called by mutect2, pindel, varscan2
- PBRM1 | c.4691del p.L1564Wfs*32 (on ENST00000296302 / NM_001366071.2; = p.L1457Wfs*32 on NM_018313.5) | Frame Shift Del (DEL) | VAF 93/174 reads (53%) | called by mutect2, pindel, varscan2
- PROC | c.972_977del p.L325_A326del | In Frame Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, varscan2
- SELENOP | c.379_380del p.L127Kfs*? | Frame Shift Del (DEL) | VAF 371/827 reads (45%) | called by mutect2, pindel, varscan2
- SNW1 | c.1325_1337del p.D442Vfs*18 | Frame Shift Del (DEL) | VAF 75/242 reads (31%) | called by mutect2, pindel, varscan2
- SWSAP1 | c.486_487del p.P163Cfs*53 (on ENST00000312423; = p.P184Cfs*53 on NM_175871.4) | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- SYTL5 | c.561del p.S189Afs*12 | Frame Shift Del (DEL) | VAF 77/123 reads (63%) | called by mutect2, pindel, varscan2
- ASB4 | c.897C>T p.R299= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV57943291; called by muse, mutect2, varscan2
- C1S | c.2001G>T p.R667= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as COSV61070202; called by muse, mutect2, varscan2
- CAVIN4 | c.675A>C p.I225= | Silent (SNP) | VAF 60/83 reads (72%) | catalogued as COSV56866682; called by muse, mutect2, varscan2
- CD40LG | c.153C>T p.D51= | Silent (SNP) | VAF 272/326 reads (83%) | catalogued as COSV65698217; called by muse, mutect2, varscan2
- ERBB4 | c.2394T>A p.L798= | Silent (SNP) | VAF 91/181 reads (50%) | catalogued as COSV61467619; called by muse, mutect2, varscan2
- FBXO4 | c.294G>A p.L98= | Silent (SNP) | VAF 283/882 reads (32%) | catalogued as COSV55851409; called by muse, mutect2, varscan2
- FMO5 | c.987C>T p.A329= | Silent (SNP) | VAF 27/243 reads (11%) | catalogued as COSV54204795; called by muse, mutect2
- GPR160 | c.312T>C p.T104= | Silent (SNP) | VAF 142/195 reads (73%) | catalogued as rs764186478, COSV63472645; called by muse, mutect2, varscan2
- IQCE | c.1110C>G p.A370= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV58076726; called by muse, mutect2, varscan2
- MAST4 | c.4734G>A p.P1578= (on ENST00000403625 / NM_001164664.2; = p.P1389= on NM_015183.3) | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as rs761038795, COSV55117296; called by muse, mutect2, varscan2
- MTDH | c.1032A>C p.S344= | Silent (SNP) | VAF 63/293 reads (22%) | catalogued as COSV60342850; called by muse, mutect2, varscan2
- NIBAN2 | c.345C>T p.A115= | Silent (SNP) | VAF 66/92 reads (72%) | catalogued as rs370542607; called by muse, mutect2, varscan2
- SHD | c.165G>A p.P55= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs368273049; called by muse, mutect2, varscan2
- SRCAP | c.3849C>T p.T1283= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV52668275; called by muse, mutect2
- TCEA3 | c.243C>T p.S81= | Silent (SNP) | VAF 144/202 reads (71%) | catalogued as rs377440841, COSV65840800; called by muse, mutect2, varscan2
- SSPOP | n.2201A>C | RNA (SNP) | VAF 44/180 reads (24%) | catalogued as COSV50486607; called by muse, mutect2
